Surgical pathology report (de-identified scan), TCGA case TCGA-DX-A7EO, project TCGA-SARC (Sarcoma), tissue source site Memorial Sloan Kettering, specimen TCGA-DX-A7EO-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]

[REDACTED]

Clinical Diagnosis and History:

Synovial sarcoma of left flank.

Specimens Submitted:

SP: Lt. flank, synovial sarcoma

DIAGNOSIS:

- 1) SKIN AND SOFT TISSUE, LEFT FLANK; EXCISION:
- BIPHASIC SYNOVIAL SARCOMA, INVOLVING SOFT TISSUE AND SKELETAL MUSCLE.
- THE TUMOR SIZE IS 7.1 CM.
- THE TUMOR IS ASSOCIATED WITH FOCAL SCLEROSIS AND FIBROSIS.
- NO APPARENT TUMOR NECROSIS SEEN.
- ALL SURGICAL MARGINS ARE FREE OF TUMOR.

NOTE: THE TUMOR CELLS SHOW AN IMMUNOSTAINING PATTERN COMPATIBLE WITH THAT SEEN IN SYNOVIAL SARCOMA (IMMUNOREACTIVITY FOR AE1:AE3 AND CMA 5.2 MAINLY SEEN IN THE EPITHELIAL COMPONENT AND VERY FOCALLY IN SPINDLE CELLS; EMA STAINING SEEN PREDOMINANTLY IN EPITHELIAL CELLS BUT ALSO IN SOME SPINDLE CELLS). MOLECULAR STUDIES FOR THE SYT-SSX FUSION TRANSCRIPT ASSOCIATED WITH T(X;18) WILL BE PERFORMED AND WILL BE REPORTED SEPARATELY.

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Stain/Procedure Name	Result	Comment
KERATIN (CAM5.2)		
AE1:AE3		
EMA		
PROLIF ANTIGEN (Ki67)		
BCL2		
CD34		
VIMENTIN		

** Continued on next page **

ICD-O-3
Sarcoma, synovial lymphatic
Site: Trunk, soft tissue
path
9043/3
C49.6
49.6
9/26/13

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

NEGATIVE CONTROL
IMMUNO RECURT

Page 2 of 2

Gross Description:

1) The specimen is received fresh, labeled, "Left flank synovial sarcoma, short stitch marks superior, long stitch posterior". It consists of a 12.0 x 1.5 cm ellipse of skin incised to a depth of 13.2 cm including 6.2 cm of subcutaneous adipose tissue and 7.0 cm of skeletal muscle. There is a long stitch marking the posterior margin and a short marking the superior margin. The specimen is inked as follows: Superior - blue, inferior - green, anterior - yellow, posterior - red, deep - black. The skin is grossly unremarkable. A 7.1 x 6.5 x 4.8 cm, well-defined, fleshy, soft tan, white intramuscular mass is present 1.6 cm from the deep surgical margin, the closest surgical margin. In reference to the other surgical margins is 0.2 cm from the inferior margin, 2.0 cm from the superior margin, 2.5 cm from the posterior margin, and 3.5 cm from the anterior margin, and 3.0 cm from the surface of the skin. The photo is sent for TPS and for and tissue was taken. Representative sections of the specimen are submitted.

Summary of Sections:

DM - deep surgical margin
INS - inferior surgical margin
SUP - superior surgical margin
PR - posterior surgical margin
ANT - anterior surgical margin
SKI - skin
MA - mass

Summary of Sections:

Part	Sect. Site	Blocks	Pieces	All
1	SKI	-	1	N
	ant	1	1	
	dem	3	3	
	inf	2	2	
	ma	8	M	
	po	2	2	
	ski	1	1	
	su	1	1	

** End of Report **

Source: NCI Genomic Data Commons file 4b1157a1-cd4a-4bb4-9a4c-b8694ee7437a (TCGA-DX-A7EO.9D1732CC-080D-4C90-AB74-02EC31824176.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).